CCDI case PBCGRJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/0799f6e4-17c1-4768-b99b-044736f3261d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 14.0 years (5,104 days).

Biospecimens (3 samples)
- Sample 0DSHSS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSHT1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSHTA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
